CCDI case PBCBGM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/62164999-7165-4d53-b205-324a9e1a2a7f

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Epithelial-myoepithelial carcinoma: ICD-O-3 morphology code: 8562/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 0.2 years (81 days).

Biospecimens (3 samples)
- Sample 0DP2CD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP2CH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP2CL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
